Somatic mutation profile of tumor specimen 0DT9NR from CCDI case PBCJJW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.8 years (6,513 days).
Specimen 0DT9NR: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4f8e931-2e64-46b1-9875-f9599dbd5584.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT9NE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/094137fd-b43b-4931-8c6d-63a6dcb5635e

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSTYK | c.2380A>G p.T794A | Missense Mutation (SNP) | VAF 30/565 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2
- EZHIP | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); called by muse, mutect2
